Surgical pathology report (de-identified scan), TCGA case TCGA-14-1452, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-1452-01A (Primary Tumor).

= tion 1 of 1: Anatomic Pathology Report

= , Auth [REDACTED] EMR EVENT Id: [REDACTED]

Patient: [REDACTED]

Accession Number: [REDACTED]

Patient Number: [REDACTED]

Date Collected: [REDACTED]

Financial Number: [REDACTED]

Date Received: [REDACTED]

Room/Bed: [REDACTED] PT: [REDACTED]

Admitting Physician: [REDACTED]

Ordering Physician: [REDACTED]

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. RIGHT FRONTAL BRAIN LESION, RESECTION, FS1A, TP1A:
- GLIOBLASTOMA (WHO GRADE IV).
2. RIGHT FRONTAL BRAIN LESION, RESECTION:
- GLIOBLASTOMA (WHO GRADE IV).

TCGA-14-1452

SPECIMEN:

1. Right frontal brain lesion.
2. Right frontal brain lesion.

CLINICAL HISTORY/OPERATIVE FINDINGS:

Brain tumor.

GROSS DESCRIPTION:

Two specimens are received, specimen #1 is received fresh for intraoperative consultation, and specimen #2 is received in formalin, each labeled with the patient's name and medical record number.

Specimen #1 is labeled "right frontal brain lesion." The specimen consists of multiple fragments of soft tan hemorrhagic tissue measuring 1.3 x 0.8 x 0.5 cm in aggregate. An intraoperative touch preparation is performed. A portion of the specimen is frozen for intraoperative consultation, and the remainder of the cryoblock is submitted in cassette "FS1A." The remainder of the specimen is entirely submitted in cassette "1B."

Specimen #2 is labeled "right frontal brain lesion." The specimen consists of multiple fragments of soft tan extensively hemorrhagic tissue measuring 4.7 x 4.3 x 1.1 cm in aggregate. Representative sections are submitted in cassettes "2A" through "2C."

OPERATIVE CONSULTATION:

FS1A, TP1A: BRAIN, RIGHT FRONTAL, BIOPSY (FROZEN SECTION, TOUCH PREPARATION):
GLIOBLASTOMA.

Source: NCI Genomic Data Commons file dfefebe8-371c-431e-a13f-1118bf2f08dd (TCGA-14-1452.F38CB64B-9649-4CC3-A14F-3EABF2C1B299.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).